Surgical pathology report (de-identified scan), TCGA case TCGA-FG-5962, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-5962-01B (Primary Tumor).

SURGICAL PATHOLOGY REPORT

Name:
Accession #:
Date of Procedure:
Date Received:
Submitting Physician:

Med. Rec #.
Location:
Race:
DOB/Sex:

FINAL DIAGNOSIS

A. TUMOR, REMOVAL:
--OLIGODENDROGLIOMA, SEE NOTE.

Note: The morphologic features of the tumor are similar to those seen in the patient's previous resection

Electronically Signed Out By By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Clinical History:

brain tumor

Specimens Submitted As:

A:TUMOR

Gross Description:

Received in formalin labeled with the patient's name and number, are multiple irregular, opaque white to pink-tan, soft, cerebriform tissue fragments measuring in aggregate 2.4 x 2.2 x 0.5 cm. Submitted in toto in one cassette.

Source: NCI Genomic Data Commons file 7b14fe56-206e-4cc9-8538-deb4a9b09b56 (TCGA-FG-5962.1ED7F628-F222-41E4-A83C-B0884C4C4D81.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).